Somatic mutation profile of tumor specimen BA3333D (aliquot aq-BA3333D) from BEATAML1.0 case 2746, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow.
Specimen BA3333D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3424450-c461-4ba1-9d62-4edf8ef4cbae.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3120D (Solid Tissue Normal), aliquot aq-BA3120D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ee213b5-9785-4fd3-a799-44aaf6a76d92

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- GATA2 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- MYH13 | c.2249T>C p.L750P | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECW1 | c.2292C>T p.N764= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs1026932363, COSV101223494; called by muse, varscan2
